CCDI case PBCBIB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/7fb09a5b-f2f1-41d3-9389-2ff54763a69a

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Craniopharyngioma: ICD-O-3 morphology code: 9350/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.4 years (3,438 days).

Biospecimens (2 samples)
- Sample 0DPJS7: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DPJSY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
